Gene-level copy-number profile of tumor specimen TCGA-2G-AAHW-01A from TCGA case TCGA-2G-AAHW, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 37.8 years (13,824 days).
Specimen TCGA-2G-AAHW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f2b94efc-2d6c-497f-9dd0-8344bfc0eef7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAHW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/754fce19-074a-42c8-a2d2-dd6e21caa0b8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 1,059; copy number 2: 14,468; copy number 3: 27,771; copy number 4: 9,922; copy number 5: 2,267; copy number 6: 2,719; copy number 7: 106; copy number 8: 376; copy number 9: 183; copy number 11: 32.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr13:52,488,993–52,587,095, 2 genes: AL137058.1, AL137058.3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 697 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:225,399,710–228,181,687, 33 genes, copy number 7–11: NYAP2, AC016717.1, AC016717.2, AC016717.3, AC068138.1, AC062015.1, MIR5702, IRS1, AC010735.2, AC010735.1, RHBDD1, AC073149.1, COL4A4, COL4A3, MFF-DT, MFF, TM4SF20, MIR5703, AGFG1, C2orf83, SCYGR3, AC064853.1, SCYGR4, SLC19A3, RNA5SP121, SNRPGP8, AC073065.1, CCL20, TDGF1P2, DAW1, AC073065.2, SPHKAP, RNU6-624P.
- chr3:50,260,303–80,442,305, 419 genes, copy number 8–9 (broad region; genes not listed).
- chr7:109,660,094–121,297,442, 127 genes, copy number 8 (broad region; genes not listed).
- chr10:19,048,801–19,790,401, 1 gene, copy number 7 (within-gene range 6–7): MALRD1.
- chr10:19,290,223–24,952,606, 84 genes, copy number 7 (broad region; genes not listed).
- chr10:24,953,241–24,953,513, 1 gene, copy number 7: AL512598.1.
- chr11:61,588,442–61,639,449, 2 genes, copy number 8: AP002754.1, RPLP0P2.
- chr11:70,270,690–71,566,735, 30 genes, copy number 7–8: PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10.

Autosomal genes at a single copy (total copy number 1): 1,059. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
